Somatic mutation profile of tumor specimen HCM-CSHL-0433-C24-01A (aliquot HCM-CSHL-0433-C24-01A-11D-A78L-36) from HCMI case HCM-CSHL-0433-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.1 years (19,015 days).
Specimen HCM-CSHL-0433-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07d70d2d-9abb-4a17-9658-62a80d4093f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0433-C24-11A (Solid Tissue Normal), aliquot HCM-CSHL-0433-C24-11A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fcc5f1a-def3-4d5d-a4b8-a95b8f6dc70b

The open-access MAF lists 66 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, 3'UTR 5, Intron 4, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 155/539 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4774C>T p.R1592* | Nonsense Mutation (SNP) | VAF 28/200 reads (14%) | catalogued as rs1057518410, COSV57432438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALOX5 | c.555-2A>T p.X185_splice | Splice Site (SNP) | VAF 35/187 reads (19%) | catalogued as COSV104428486; called by muse, mutect2, varscan2
- ALOXE3 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV59076749; called by muse, mutect2, varscan2
- ARSI | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754848958; called by muse, mutect2, varscan2
- ATP13A1 | c.3307G>A p.V1103I | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.699); catalogued as rs763580040, COSV99179598; called by muse, mutect2, varscan2
- CACTIN | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 140/706 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV50266552; called by muse, mutect2, varscan2
- DDX11 | c.2209C>T p.Q737* (on ENST00000545668 / NM_152438.2; = p.Q687* on NM_004399.3) | Nonsense Mutation (SNP) | VAF 271/881 reads (31%) | catalogued as rs757776704; called by muse, mutect2, varscan2
- FXN | c.15A>C p.K5N (on ENST00000377270; = p.K80N on NM_000144.5) | Missense Mutation (SNP) | VAF 198/501 reads (40%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs1169387979; called by muse, mutect2, varscan2
- HMOX2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs1298327866; called by muse, mutect2, varscan2
- KCNJ5 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57963912; called by muse, mutect2, varscan2
- KIF21B | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754732012, COSV59760556; called by muse, mutect2, varscan2
- LYST | c.6775G>A p.V2259I | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs773927032; called by muse, mutect2, varscan2
- MYT1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs903442892, COSV100114387, COSV60513530; called by muse, mutect2, varscan2
- NCOA1 | c.3190G>A p.G1064R | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56055792; called by muse, mutect2
- PALLD | c.2902G>A p.V968I (on ENST00000505667 / NM_001166108.2; = p.V951I on NM_016081.4) | Missense Mutation (SNP) | VAF 94/486 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs551420048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA9 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 144/841 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV100969368; called by muse, mutect2, varscan2
- PSG1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 124/696 reads (18%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.623); catalogued as rs150536125; called by muse, varscan2
- SMAD4 | c.1089T>G p.C363W | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747670; called by muse, mutect2, varscan2
- SPATC1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 142/783 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs572315628, COSV66299115; called by muse, mutect2, varscan2
- STAT3 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 108/743 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52890394; called by muse, mutect2, varscan2
- UBP1 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs770784996; called by muse, mutect2
- ZNF438 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467708296; called by muse, mutect2, varscan2
- ZNF804A | c.2908C>G p.L970V | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV56473326; called by muse, mutect2, varscan2
- ACTRT1 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ADAMTS13 | c.3968G>A p.G1323E | Missense Mutation (SNP) | VAF 267/854 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ADCY10 | c.394A>C p.T132P | Missense Mutation (SNP) | VAF 173/882 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ARL6 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHERP | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COL4A6 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CPE | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 72/447 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- HMSD | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IL2RB | c.1607A>T p.Y536F | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JARID2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- KRTAP9-3 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 113/719 reads (16%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MAIP1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MED24 | c.672-2A>G p.X224_splice | Splice Site (SNP) | VAF 141/417 reads (34%) | called by muse, mutect2, varscan2
- MTMR11 | c.1825C>T p.L609F (on ENST00000439741 / NM_001145862.2; = p.L537F on NM_181873.3) | Missense Mutation (SNP) | VAF 108/655 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEA | c.6898T>G p.L2300V | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- P4HTM | c.1422_1423dup p.A475Gfs*59 (on ENST00000383729 / NM_177939.3; = p.A536Gfs*59 on NM_177938.2) | Frame Shift Ins (INS) | VAF 148/1075 reads (14%) | called by mutect2, pindel, varscan2
- RC3H1 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STYXL2 | c.1457A>T p.E486V | Missense Mutation (SNP) | VAF 112/690 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM51 | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 65/538 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- UTRN | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ZNF548 | c.1464A>C p.R488S | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABCA3 | c.1902G>A p.K634= | Silent (SNP) | VAF 113/600 reads (19%) | called by muse, mutect2, varscan2
- CLCN2 | c.126C>T p.R42= | Silent (SNP) | VAF 129/717 reads (18%) | called by muse, mutect2, varscan2
- GAD2 | c.114C>T p.G38= | Silent (SNP) | VAF 100/757 reads (13%) | catalogued as rs1235686175, COSV99394122; called by muse, mutect2, varscan2
- KCNG4 | c.642G>A p.P214= | Silent (SNP) | VAF 109/758 reads (14%) | catalogued as rs752941174; called by muse, mutect2, varscan2
- NACAD | c.414G>A p.A138= | Silent (SNP) | VAF 60/395 reads (15%) | catalogued as rs764877585; called by muse, mutect2, varscan2
- OR2T2 | c.660G>A p.T220= | Silent (SNP) | VAF 197/1259 reads (16%) | catalogued as rs770828092, COSV61617719; called by muse, mutect2, varscan2
- RFPL4B | c.201C>T p.S67= | Silent (SNP) | VAF 98/520 reads (19%) | catalogued as rs112616941; called by muse, mutect2, varscan2
- TP53BP1 | c.5412A>G p.L1804= | Silent (SNP) | VAF 60/339 reads (18%) | catalogued as rs1169949685; called by muse, mutect2, varscan2
- URGCP | c.2616G>A p.K872= (on ENST00000453200 / NM_001077663.3; = p.K863= on NM_017920.4) | Silent (SNP) | VAF 101/582 reads (17%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1875C>T p.N625= | Silent (SNP) | VAF 149/830 reads (18%) | catalogued as rs566297803, COSV60089798; called by muse, mutect2, varscan2
- CD81 | c.561+45G>A | Intron (SNP) | VAF 143/716 reads (20%) | catalogued as rs368913200; called by muse, mutect2, varscan2
- CHRNA7 | c.350+394A>G | Intron (SNP) | VAF 79/451 reads (18%) | catalogued as rs986078370; called by muse, mutect2, varscan2
- CPN1 | c.*20C>A | 3'UTR (SNP) | VAF 125/748 reads (17%) | called by muse, mutect2, varscan2
- FAS | c.*989A>T | 3'UTR (SNP) | VAF 49/304 reads (16%) | called by muse, mutect2, varscan2
- FLT4 | c.2648-92C>T | Intron (SNP) | VAF 102/418 reads (24%) | catalogued as rs1438549116; called by muse, mutect2, varscan2
- FOXP2 | c.*1953A>G | 3'UTR (SNP) | VAF 40/278 reads (14%) | called by muse, mutect2, varscan2
- H3-2 | c.*94G>A | 3'UTR (SNP) | VAF 192/1459 reads (13%) | called by muse, mutect2, varscan2
- MIR544A | n.54G>C | RNA (SNP) | VAF 54/300 reads (18%) | called by muse, mutect2, varscan2
- OBP2A | c.*55G>A | 3'UTR (SNP) | VAF 22/234 reads (9%) | catalogued as rs200533613; called by muse, mutect2
- TBX5 | c.-25G>A | 5'UTR (SNP) | VAF 210/957 reads (22%) | catalogued as rs748222016; called by muse, mutect2, varscan2
- TRPV2 | c.2115-43C>T | Intron (SNP) | VAF 49/255 reads (19%) | catalogued as rs370803898; called by muse, mutect2, varscan2
